TARGET case TARGET-15-SJMPAL012420 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/da3d2ca6-287d-4f18-b489-b96b15b4b5cc

Demographics
Sex at birth: female; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.7 years (1,001 days); Year of diagnosis: 2004; Days to last follow up: 4,185 days (11.5 years).

Follow-up (1 entry)
- Days to follow up: 4,185 days (11.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 4,185; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 116 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL012420-09A, TARGET-15-SJMPAL012420-09A.1, TARGET-15-SJMPAL012420-09A.2 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012420-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 4185
- Protocol: St. Jude
- WBC at Diagnosis: 116
- Initial Therapy: AML
- Karyotype: 46,XX,der(2)?inv(2)(p11.2q13)t(2;14)(14qter->14q32.1::2p?->2qter),der(14)t(2;14)(14pter->14q32.1:: 2q13->2p12->2pter)[19]/46,XX[1]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
